Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7609, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7609-01A (Primary Tumor).

Microscopic

Sections demonstrate a markedly hypercellular glial neoplasm consisting of atypical cells that resemble astrocytes. There is also a significant oligodendroglial component. The neoplastic cells demonstrate pleomorphic and often bizarre nuclei. In some areas, there is a predominance of gemistocytes. The neoplastic cells diffusely infiltrate adjacent gray and white matter. Scattered mitotic figures are seen. Occasional foci of early spontaneous necrosis as well as microvascular proliferation are identified. These histologic features are consistent with an anaplastic oligoastrocytoma

Addendum

Sections demonstrate a markedly hypercellular glial neoplasm consisting of atypical cells that resemble astrocytes. There is also a significant oligodendroglial component. The neoplastic cells demonstrate pleomorphic and often bizarre nuclei. In some areas, there is a predominance of gemistocytes scattered mitotic figures are seen. Occasional foci of early spontaneous necrosis as well as microvascular proliferation are identified. These histologic features are consistent with an aaplastic oligoastrocytoma

The MIB-1 labeling index ranges up to 10.2% in the most proliferative regions of tumor.

Diagnosis

Anaplastic oligoastrocytoma, astrocytoma predominant

Source: NCI Genomic Data Commons file fabb38ca-aa79-42c2-92b9-6c231ac7590e (TCGA-HT-7609.D6E4B412-5A31-4CAC-BE39-CE4342F73BE6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).